HCMI case HCM-BROD-0048-C71 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4b9b3130-2483-4e5d-8c4d-e225590a5cd2

Demographics
Sex at birth: male; Year of birth: 1950; Vital status: Alive.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 66.2 years (24,164 days); WHO CNS grade: Grade IV; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Pathology details: Necrosis present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -5 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 29 days; Days to treatment end: 60 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 29 days; Days to treatment end: 60 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 109 days; Days to treatment end: 508 days (1.4 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (3 entries)
- Days to follow up: 8 days; Karnofsky performance status: 80.
- Days to follow up: 1,073 days (2.9 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contacts recording only the day: day 0, day 676.

Molecular and laboratory tests
- IDH1 / IDH2 (Targeted Sequencing): Negative.
- MGMT methylation: Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 80.4 kg.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Glioblastoma.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0048-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-BROD-0048-C71-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 61; Percent tumor nuclei: 77; Percent normal cells: 18; Percent necrosis: 12; Percent stromal cells: 9; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
  Slide HCM-BROD-0048-C71-01A-01-S1-HE: Section location: Top; Percent tumor cells: 52; Percent tumor nuclei: 71; Percent normal cells: 21; Percent necrosis: 10; Percent stromal cells: 17; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample HCM-BROD-0048-C71-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0048-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
